Somatic mutation profile of tumor specimen TCGA-20-0996-01A (aliquot TCGA-20-0996-01A-03W-0486-08) from TCGA case TCGA-20-0996, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 59.1 years (21,572 days).
Specimen TCGA-20-0996-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9e1e3825-2350-4737-86a2-79b9ffd2e621.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-20-0996-10A (Blood Derived Normal), aliquot TCGA-20-0996-10A-01W-0486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/949a7437-bdf4-4721-9520-b84d7e87c19f

The open-access MAF lists 31 somatic variants for this specimen: 29 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Splice Region 2, Frame Shift Ins 2, 5'Flank 1, Nonsense Mutation 1, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 217/493 reads (44%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AKAP1 | c.216dup p.S73Qfs*41 | Frame Shift Ins (INS) | VAF 4/42 reads (10%) | catalogued as rs771272447; called by pindel, varscan2
- AKAP11 | c.5183T>C p.I1728T | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs1424735169, COSV99214014; called by muse, mutect2
- ATG14 | c.1029A>T p.K343N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.161); catalogued as COSV99902838; called by muse, mutect2, varscan2
- CCDC80 | c.550A>T p.I184F | Missense Mutation (SNP) | VAF 78/182 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.773); catalogued as COSV99244879; called by muse, mutect2, varscan2
- CCDC86 | c.635A>C p.K212T | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV99920167; called by muse, mutect2, varscan2
- DCAF12L1 | c.534G>T p.Q178H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100948340; called by muse, mutect2, varscan2
- EIF1AX | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63309258, COSV63309273, COSV63309318; called by muse, mutect2, varscan2
- EMC2 | c.500A>G p.N167S | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs753999031, COSV55210057; called by muse, mutect2
- FHL5 | c.682C>G p.P228A | Missense Mutation (SNP) | VAF 126/293 reads (43%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.536); catalogued as rs777449624, COSV100459500; called by muse, mutect2, varscan2
- GTPBP2 | c.753C>G p.S251R | Missense Mutation (SNP) | VAF 16/270 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.221); catalogued as COSV100200015; called by muse, mutect2
- HEATR6 | c.3352G>A p.D1118N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as COSV99482403; called by muse, mutect2, varscan2
- IFT140 | c.1639G>C p.D547H | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101276448; called by muse, mutect2, varscan2
- LILRA2 | c.1078del p.A360Qfs*8 | Frame Shift Del (DEL) | VAF 38/124 reads (31%) | catalogued as rs34018665; called by pindel, varscan2
- MS4A12 | c.778A>T p.N260Y | Missense Mutation (SNP) | VAF 62/140 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as COSV99189017; called by muse, varscan2
- MTAP | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 84/192 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as COSV66477603; called by muse, varscan2
- MYH1 | c.534C>T p.T178= | Splice Region (SNP) | VAF 12/153 reads (8%) | catalogued as rs112621883, COSV56844906; called by muse, mutect2
- NUP88 | c.1483T>C p.L495= | Splice Region (SNP) | VAF 69/138 reads (50%) | catalogued as COSV99851777; called by muse, mutect2, varscan2
- OR5K3 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 37/825 reads (4%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.935); catalogued as rs200376148, COSV101051690; called by muse, mutect2
- POLR1B | c.219C>G p.I73M | Missense Mutation (SNP) | VAF 45/81 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.621); catalogued as COSV99637886; called by muse, mutect2, varscan2
- PTPRD | c.191T>C p.V64A | Missense Mutation (SNP) | VAF 122/303 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100645174, COSV100647182; called by muse, mutect2, varscan2
- RAPGEF1 | c.2219A>G p.Y740C | Missense Mutation (SNP) | VAF 47/94 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100940633; called by muse, mutect2, varscan2
- RELN | c.10306A>C p.M3436L | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.082); catalogued as COSV100633989; called by muse, mutect2
- SBNO2 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs762097002, COSV100684652; called by muse, mutect2, varscan2
- VSIG4 | c.769G>T p.V257L | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV101038187; called by muse, mutect2, varscan2
- VXN | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 9/125 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1435329858, COSV100560036; called by muse, mutect2
- WNK3 | c.1907T>C p.L636P | Missense Mutation (SNP) | VAF 81/168 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as COSV100671558; called by muse, mutect2, varscan2
- ZNF286A | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 69/142 reads (49%) | catalogued as COSV101224806; called by muse, mutect2, varscan2
- XBP1 | c.502dup p.R168Kfs*219 | Frame Shift Ins (INS) | VAF 95/246 reads (39%) | called by mutect2, pindel, varscan2
- MAGEA10 | c.342G>A p.E114= | Silent (SNP) | VAF 142/307 reads (46%) | catalogued as COSV99726760; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499004 T>C | 5'Flank (SNP) | VAF 10/43 reads (23%) | called by muse, mutect2, varscan2
